Gene-level copy-number profile of tumor specimen TCGA-CS-4941-01A from TCGA case TCGA-CS-4941, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Brain, NOS; Tumor grade: G3; Age at diagnosis: 67.3 years (24,578 days).
Specimen TCGA-CS-4941-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.acdbe261-edf6-4a62-b2b1-bb9b0215764c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CS-4941-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9dcff0b5-ad7c-40ec-a3ee-903f9fd421d4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,896; copy number 2: 43,483; copy number 3: 8,305; copy number 6: 41; copy number 8: 4; copy number 11: 2; copy number 12: 9; copy number 14: 2; copy number 28: 18; copy number 34: 1; copy number 39: 20; copy number 43: 39.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CS-4941-01A-01D-1466-01): tumor purity 0.62, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 136 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:52,891,837–53,188,938, 4 genes, copy number 8: SGO1P2, AC074397.1, POM121L12, HAUS6P1.
- chr7:54,933,699–55,713,252, 17 genes, copy number 39: AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P.
- chr7:56,805,336–57,275,197, 41 genes, copy number 6: CICP28, AC118758.2, AC118758.1, AC069152.1, MIR4283-1, TNRC18P3, SLC29A4P1, PHKG1P4, AC122133.1, ZNF479, AC099654.11, AC099654.2, AC099654.5, AC099654.8, MTATP6P8, MTCO3P10, AC099654.4, MTND4LP32, MTND4P4, MTND5P6, MTND6P29, MTCYBP29, GUSBP10, MTND1P4, MTND2P6, MTCO1P10, MTCO2P10, AC099654.6, MTATP6P10, MTCO3P4, AC099654.9, AC099654.7, MTND4P5, MTND5P7, AC099654.10, MTCYBP5, GUSBP12, AC099654.1, RNU7-157P, AC099654.12, AC099654.3.
- chr7:57,599,794–57,655,392, 9 genes, copy number 12: NCOR1P3, AC064862.6, AC064862.7, BSNDP4, AC064862.1, AC064862.5, AC064862.2, AC064862.4, AC064862.3.
- chr12:39,755,025–40,106,089, 2 genes, copy number 14 (within-gene range 1–14): SLC2A13, AC121336.1.
- chr12:57,723,761–57,846,729, 18 genes, copy number 28: AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2.
- chr12:66,292,683–66,343,643, 2 genes, copy number 11 (within-gene range 11–40): RN7SKP166, HELB.
- chr12:68,746,125–70,637,440, 43 genes, copy number 34–43 (within-gene range 2–43): SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1.

Autosomal genes at a single copy (total copy number 1): 5,510. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
